Gene-level copy-number profile of tumor specimen C3N-01175-01 from CPTAC case C3N-01175, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 60.8 years (22,205 days).
Specimen C3N-01175-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6d9bbe26-49f1-4c08-b779-12b0926233ac.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01175-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/72bff1b7-e27b-40bb-b851-824ba457a22b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 23,771; copy number 2: 34,618.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,294–29,934,286, 8 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr6:32,549,940–32,560,022, 2 genes (within-gene range 0–1): RNU1-61P, HLA-DRB6.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr17:46,503,946–46,579,691, 5 genes: RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 21,427. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
